Somatic mutation profile of tumor specimen ALCH-B0DW-TTP1-A (aliquot ALCH-B0DW-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0DW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.1 years (27,434 days).
Specimen ALCH-B0DW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ef5607d-cad3-4c6e-8f76-93752177c4ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0DW-NB1-A (Blood Derived Normal), aliquot ALCH-B0DW-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ace5ef1c-ead9-4e49-9016-a1606c631449

The open-access MAF lists 153 somatic variants for this specimen: 108 protein-altering or splice-affecting, 27 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 27, RNA 7, Intron 7, Frame Shift Del 6, Splice Site 4, Nonsense Mutation 4, Frame Shift Ins 3, Splice Region 3, 5'Flank 2, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 104/305 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM10 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 38/594 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV53051272; called by muse, mutect2
- ADAMTS16 | c.1757A>G p.H586R | Missense Mutation (SNP) | VAF 55/256 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs776072487; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2971G>A p.V991I | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.138); catalogued as rs1178552772; called by muse, mutect2, varscan2
- ADARB2 | c.1792G>A p.V598I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as rs376165135; called by muse, mutect2, varscan2
- ADGB | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs746736928; called by muse, mutect2, varscan2
- ATM | c.5189G>C p.R1730P | Missense Mutation (SNP) | VAF 105/521 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.082); catalogued as CM121257; called by muse, mutect2, varscan2
- ATP2B4 | c.2969G>T p.G990V | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs760671233; called by muse, mutect2, varscan2
- ATXN1L | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as rs1490267114; called by muse, mutect2, varscan2
- BFAR | c.916C>G p.Q306E | Missense Mutation (SNP) | VAF 77/233 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753189254; called by muse, mutect2, varscan2
- CAMK4 | c.1029C>A p.S343R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV56660873; called by muse, mutect2, varscan2
- CCL19 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as COSV100323175; called by muse, mutect2, varscan2
- CLASP2 | c.1184+1G>A p.X395_splice | Splice Site (SNP) | VAF 30/99 reads (30%) | catalogued as rs768027167; called by muse, mutect2, varscan2
- COL6A1 | c.1401C>T p.G467= | Splice Region (SNP) | VAF 40/172 reads (23%) | catalogued as rs774598083; called by muse, mutect2, varscan2
- DMRTC2 | c.266G>C p.R89T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as COSV99523336; called by muse, mutect2, varscan2
- DST | c.15522del p.H5175Ifs*40 (on ENST00000361203 / NM_001374722.1; = p.H2763Ifs*40 on NM_015548.5) | Frame Shift Del (DEL) | VAF 51/228 reads (22%) | catalogued as COSV54995678; called by mutect2, pindel, varscan2
- FAM171A1 | c.2587G>C p.D863H | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV65313466; called by muse, mutect2, varscan2
- HK2 | c.2537G>T p.R846L | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51875182; called by muse, mutect2, varscan2
- LOXHD1 | c.3829C>A p.R1277S | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201518726; called by muse, varscan2
- LRRC4C | c.883C>G p.R295G | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV53438355; called by muse, mutect2, varscan2
- LTBP4 | c.3013G>A p.D1005N (on ENST00000308370 / NM_001042544.1; = p.D968N on NM_003573.2) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52584899; called by muse, mutect2, varscan2
- MGA | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs754560732, COSV54951016; called by muse, mutect2
- MNDA | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 111/429 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs142166364; called by muse, mutect2, varscan2
- MUC5B | c.5768C>T p.T1923M | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as rs142667139; called by muse, mutect2, varscan2
- MYH1 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV56846687; called by muse, mutect2, varscan2
- NPAP1 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.893); catalogued as COSV61505137; called by muse, mutect2, varscan2
- NPAP1 | c.2717G>T p.G906V | Missense Mutation (SNP) | VAF 53/207 reads (26%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.925); catalogued as rs368505553, COSV61512261; called by muse, mutect2, varscan2
- OPRPN | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.048); catalogued as COSV68193475; called by muse, mutect2, varscan2
- OR1N2 | c.187T>C p.Y63H | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200351236; called by muse, mutect2, varscan2
- OR2AJ1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs895927038; called by muse, varscan2
- OR4P4 | c.869C>A p.T290K | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV58920456; called by muse, mutect2, varscan2
- PAPSS2 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 119/489 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs544558219; called by muse, mutect2, varscan2
- PLA2G4C | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62785616; called by muse, mutect2, varscan2
- PRDM9 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 96/361 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV57006122; called by muse, mutect2, varscan2
- RBM10 | c.1161-1G>A p.X387_splice | Splice Site (SNP) | VAF 66/134 reads (49%) | catalogued as COSV100238488, COSV61310422; called by muse, mutect2, varscan2
- RHD | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs555567027, CM057731, COSV59646553; called by muse, mutect2, varscan2
- SIMC1 | c.1609C>T p.L537= (on ENST00000443967 / NM_001308196.1; = p.L122= on NM_198567.5) | Splice Region (SNP) | VAF 46/230 reads (20%) | catalogued as rs370624776; called by muse, mutect2, varscan2
- SORCS1 | c.3484G>T p.A1162S | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs774332489; called by muse, mutect2, varscan2
- SPAG17 | c.1593C>G p.H531Q | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.08); catalogued as rs752450603; called by muse, mutect2, varscan2
- SPEG | c.7564G>T p.A2522S | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs573748230; called by muse, mutect2, varscan2
- SUPV3L1 | c.1166G>T p.G389V | Missense Mutation (SNP) | VAF 118/462 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1272624950; called by muse, mutect2, varscan2
- TBC1D32 | c.2157+1G>T p.X719_splice | Splice Site (SNP) | VAF 52/140 reads (37%) | catalogued as rs1563044335; called by muse, mutect2, varscan2
- TENM2 | c.7024G>A p.E2342K (on ENST00000518659 / NM_001122679.2; = p.E2103K on NM_001080428.3) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs1016581373; called by muse, mutect2, varscan2
- ZPBP | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50422345; called by muse, mutect2, varscan2
- ZSCAN18 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99558952; called by muse, mutect2, varscan2
- ALOX5 | c.770dup p.V258Gfs*31 | Frame Shift Ins (INS) | VAF 40/183 reads (22%) | called by mutect2, pindel, varscan2
- ANKS1A | c.2528G>T p.R843I | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGEF10L | c.1642dup p.Y548Lfs*3 | Frame Shift Ins (INS) | VAF 34/161 reads (21%) | called by mutect2, varscan2
- ARHGEF10L | c.1643delinsTC p.Y548Ffs*3 | Frame Shift Ins (INS) | VAF 39/201 reads (19%) | called by mutect2*, pindel, varscan2*
- ATN1 | c.3472C>T p.Q1158* | Nonsense Mutation (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- ATN1 | c.3566C>T p.P1189L | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- CACNA1G | c.4087G>T p.V1363L | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC102B | c.750G>T p.L250F | Missense Mutation (SNP) | VAF 157/569 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- CCN3 | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.771); called by muse, mutect2
- CCR1 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHKB | c.102del p.K34Nfs*36 | Frame Shift Del (DEL) | VAF 26/126 reads (21%) | called by mutect2, pindel, varscan2
- CR2 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- CSPG4 | c.1798G>A p.G600S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCHS1 | c.8239G>A p.E2747K | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FCGBP | c.6440G>T p.W2147L | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); called by muse, varscan2
- GOLGA8K | c.740G>C p.G247A | Missense Mutation (SNP) | VAF 80/207 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GPR148 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- GSTA5 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 110/380 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HAS2 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 77/368 reads (21%) | called by muse, mutect2, varscan2
- HIPK1 | c.3611T>G p.I1204S (on ENST00000369558 / NM_001369806.1; = p.I810S on NM_181358.2) | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- IGKV2D-24 | c.182T>A p.L61H | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV6-21 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 93/352 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KCNMA1 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 155/656 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- LSAMP | c.135G>C p.Q45H | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- LTBP1 | c.4634C>G p.T1545R (on ENST00000404816 / NM_206943.4; = p.T1219R on NM_000627.4) | Missense Mutation (SNP) | VAF 92/367 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MDN1 | c.6424G>T p.V2142L | Missense Mutation (SNP) | VAF 101/282 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MIEF2 | c.1101C>A p.C367* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- MINPP1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 163/522 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MTTP | c.2399G>T p.G800V | Missense Mutation (SNP) | VAF 139/447 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFATC1 | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NPR3 | c.892G>A p.G298R | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR5A2 | c.64G>T p.G22C (on ENST00000367362 / NM_205860.3; = p.V22L on NM_003822.5) | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NTRK2 | c.1159+1G>A p.X387_splice | Splice Site (SNP) | VAF 79/373 reads (21%) | called by muse, mutect2, varscan2
- OR52K1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ORC3 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PBXIP1 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2
- PCDH10 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- PCDH11Y | c.1281G>T p.R427S (on ENST00000400457 / NM_032973.2; = p.R416S on NM_032971.3) | Missense Mutation (SNP) | VAF 188/355 reads (53%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PCDHGA3 | c.1769A>T p.K590M | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHGA6 | c.1769A>T p.K590M | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDP1 | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 123/280 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- PLD5 | c.463G>T p.D155Y (on ENST00000442594; = p.D93Y on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/394 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PLSCR5 | c.494T>A p.V165D | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PRDM15 | c.-200A>T | Splice Region (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- PUDP | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 87/166 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PXDNL | c.2473C>T p.R825C | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.244); called by muse, mutect2
- RAD1 | c.655C>A p.Q219K | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RANBP9 | c.1464del p.S489Afs*4 | Frame Shift Del (DEL) | VAF 114/440 reads (26%) | called by mutect2, pindel, varscan2
- RAPGEF5 | c.1492C>T p.P498S (on ENST00000401957 / NM_001367602.2; = p.P801S on NM_012294.5) | Missense Mutation (SNP) | VAF 94/335 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- REG3G | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SETD2 | c.913del p.T305Qfs*35 | Frame Shift Del (DEL) | VAF 70/301 reads (23%) | called by mutect2, pindel, varscan2
- SMTN | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SP4 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 98/381 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPANXN3 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- SPTB | c.1361T>A p.L454Q | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTY2D1 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- STIM1 | c.565A>T p.K189* | Nonsense Mutation (SNP) | VAF 80/316 reads (25%) | called by muse, mutect2, varscan2
- TWIST1 | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UFSP2 | c.135_144del p.L46Tfs*20 | Frame Shift Del (DEL) | VAF 92/388 reads (24%) | called by mutect2, pindel, varscan2
- UGT2B11 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 138/565 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ZNF155 | c.627_628del p.C209Wfs*5 | Frame Shift Del (DEL) | VAF 94/444 reads (21%) | called by pindel, varscan2
- ZNF676 | c.301A>G p.R101G (on ENST00000650058; = p.R69G on NM_001001411.3) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF729 | c.3631A>T p.T1211S | Missense Mutation (SNP) | VAF 130/480 reads (27%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CCDC168 | c.15180G>A p.Q5060= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as rs1027789799; called by muse, mutect2, varscan2
- CLN3 | c.1197G>C p.S399= (on ENST00000360019 / NM_001286104.2; = p.S423= on NM_000086.2) | Silent (SNP) | VAF 67/280 reads (24%) | called by muse, mutect2, varscan2
- CPA3 | c.834G>A p.E278= | Silent (SNP) | VAF 34/426 reads (8%) | called by muse, mutect2
- CSF1R | c.144G>C p.V48= | Silent (SNP) | VAF 63/248 reads (25%) | called by muse, mutect2, varscan2
- FLNB | c.4380G>A p.L1460= | Silent (SNP) | VAF 9/181 reads (5%) | called by muse, mutect2
- FSD1 | c.762A>T p.A254= | Silent (SNP) | VAF 51/240 reads (21%) | called by muse, mutect2, varscan2
- GKN1 | c.165C>T p.N55= | Silent (SNP) | VAF 86/307 reads (28%) | catalogued as rs145778324; called by muse, mutect2, varscan2
- HIPK1 | c.1707A>T p.T569= | Silent (SNP) | VAF 64/223 reads (29%) | called by muse, mutect2, varscan2
- INPP4A | c.132C>A p.P44= | Silent (SNP) | VAF 73/339 reads (22%) | called by muse, mutect2, varscan2
- ITPR1 | c.5124G>A p.P1708= (on ENST00000354582; = p.P1702= on NM_001168272.2) | Silent (SNP) | VAF 76/273 reads (28%) | catalogued as rs759857013, COSV56967141; called by muse, mutect2, varscan2
- KIAA1217 | c.3303A>G p.A1101= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as rs754214098; called by muse, mutect2, varscan2
- KREMEN2 | c.99G>C p.L33= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99566874; called by muse, mutect2, varscan2
- MACF1 | c.13434G>A p.L4478= (on ENST00000372915; = p.L2411= on NM_012090.5) | Silent (SNP) | VAF 74/331 reads (22%) | called by muse, mutect2, varscan2
- MYH2 | c.3652C>A p.R1218= | Silent (SNP) | VAF 135/471 reads (29%) | catalogued as rs1187271694, COSV55435050; called by muse, mutect2, varscan2
- NAV3 | c.1290G>T p.L430= | Silent (SNP) | VAF 124/445 reads (28%) | called by muse, mutect2, varscan2
- OPRPN | c.321C>T p.F107= | Silent (SNP) | VAF 89/291 reads (31%) | catalogued as COSV68192797; called by muse, mutect2, varscan2
- OR52E2 | c.57C>T p.I19= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV100384590; called by muse, mutect2, varscan2
- PCDH15 | c.1653G>C p.G551= | Silent (SNP) | VAF 155/563 reads (28%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.2676C>T p.S892= | Silent (SNP) | VAF 108/403 reads (27%) | catalogued as rs199624636, COSV53856932; called by muse, mutect2, varscan2
- PTCH1 | c.3258G>T p.L1086= | Silent (SNP) | VAF 71/305 reads (23%) | called by muse, varscan2
- RREB1 | c.3651G>A p.G1217= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1620C>G p.G540= (on ENST00000454036 / NM_001134771.2; = p.G517= on NM_020708.5) | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- SLC8A1 | c.2622C>T p.N874= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs187957282; called by muse, mutect2, varscan2
- TMC2 | c.2043C>A p.P681= | Silent (SNP) | VAF 65/311 reads (21%) | catalogued as COSV100727830, COSV62650676; called by muse, mutect2, varscan2
- WDR33 | c.1299C>T p.L433= | Silent (SNP) | VAF 24/294 reads (8%) | catalogued as rs145850509; called by muse, mutect2
- XIRP2 | c.4216C>A p.R1406= (on ENST00000628543; = p.R1581= on NM_152381.6) | Silent (SNP) | VAF 106/329 reads (32%) | catalogued as COSV54709613; called by muse, mutect2, varscan2
- ZFHX4 | c.2274G>A p.P758= | Silent (SNP) | VAF 71/333 reads (21%) | catalogued as rs917994744, COSV51491814; called by muse, mutect2, varscan2
- AC244517.10 | c.36-9936C>A | Intron (SNP) | VAF 61/273 reads (22%) | called by muse, mutect2, varscan2
- CDCA7 | c.147+423T>A | Intron (SNP) | VAF 54/187 reads (29%) | called by muse, mutect2
- EI24P4 | n.968G>T | RNA (SNP) | VAF 135/462 reads (29%) | called by muse, mutect2, varscan2
- FLT4 | c.2850+33G>T | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- FYCO1 | chr3:45915476 del TCAG | 3'Flank (DEL) | VAF 25/97 reads (26%) | called by pindel, varscan2
- MOCS1 | chr6:39934480 C>A | 5'Flank (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- MSC-AS1 | n.326C>A | RNA (SNP) | VAF 128/574 reads (22%) | called by muse, mutect2, varscan2
- PCMT1 | c.334+760T>A | Intron (SNP) | VAF 145/347 reads (42%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158710 C>A | 5'Flank (SNP) | VAF 42/210 reads (20%) | called by muse, mutect2, varscan2
- SLC19A3 | c.150+19A>G | Intron (SNP) | VAF 84/287 reads (29%) | catalogued as rs1369870143; called by muse, mutect2, varscan2
- SLC9B1P1 | n.453G>T | RNA (SNP) | VAF 82/260 reads (32%) | called by muse, mutect2, varscan2
- SMPD4BP | n.1453G>A | RNA (SNP) | VAF 8/149 reads (5%) | catalogued as rs1267781436; called by muse, mutect2
- SNORD115-4 | n.79G>T | RNA (SNP) | VAF 83/333 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.4018del | RNA (DEL) | VAF 30/90 reads (33%) | called by mutect2, pindel, varscan2
- TUBB7P | n.205G>A | RNA (SNP) | VAF 60/199 reads (30%) | called by muse, mutect2, varscan2
- XKR4 | c.806+60966T>A | Intron (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
- ZFX | c.58+906G>T | Intron (SNP) | VAF 36/57 reads (63%) | called by muse, mutect2, varscan2
- ZNF730 | c.-11G>T | 5'UTR (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
